Gene-level copy-number profile of tumor specimen TCGA-36-1574-01A from TCGA case TCGA-36-1574, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.9 years (17,847 days).
Specimen TCGA-36-1574-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a42c583f-320d-4082-bd9f-c1961aef2127.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1574-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/baab3aaf-afb4-4cf1-b2c7-6dfdbbcf668f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,410; copy number 2: 33,423; copy number 3: 9,972; copy number 4: 576; copy number 5: 345; copy number 6: 67; copy number 7: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1574-01): tumor purity 0.87, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 434 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:132,750,819–132,875,046, 8 genes, copy number 5–6: SEPTIN8, SOWAHA, AC004775.1, SHROOM1, RNA5SP192, GDF9, UQCRQ, LEAP2.
- chr8:110,555,408–143,384,221, 415 genes, copy number 5–7 (broad region; genes not listed).
- chr11:74,330,316–74,498,533, 11 genes, copy number 5 (within-gene range 3–5): PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2.

Autosomal genes at a single copy (total copy number 1): 15,410. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
